Somatic mutation profile of tumor specimen TCGA-05-4426-01A (aliquot TCGA-05-4426-01A-01D-1265-08) from TCGA case TCGA-05-4426, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.4 years (26,084 days).
Specimen TCGA-05-4426-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11ca7d53-61bd-4567-8e24-0712bf71a43b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4426-10A (Blood Derived Normal), aliquot TCGA-05-4426-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70ccbc99-2137-4eb2-8466-dfc50ca0cb00

The open-access MAF lists 46 somatic variants for this specimen: 40 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Nonsense Mutation 5, Silent 5, 5'Flank 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-2A>T p.X51_splice | Splice Site (SNP) | VAF 10/17 reads (59%) | hotspot (GDC flag); catalogued as CS014762, CS127043, COSV58692638, COSV58692823, COSV58707376; called by muse, mutect2, varscan2
- ANKRD34A | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV100041268, COSV60162193; called by muse, mutect2, varscan2
- ARRB2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777598057, COSV52619343; called by muse, mutect2, varscan2
- ASL | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs868834862, CM141244, COSV59189662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCNA2 | c.604A>T p.K202* | Nonsense Mutation (SNP) | VAF 58/152 reads (38%) | catalogued as COSV52659970; called by muse, mutect2, varscan2
- CCPG1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV51244400; called by muse, mutect2, varscan2
- CREBBP | c.5266C>T p.Q1756* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV52131473; called by muse, mutect2, varscan2
- CSE1L | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as COSV53705492; called by muse, mutect2
- CYP4F8 | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57855674; called by muse, mutect2, varscan2
- DCTN1 | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100720850, COSV62621648; called by muse, mutect2, varscan2
- DENND3 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV52807577; called by muse, mutect2, varscan2
- EXPH5 | c.1565G>A p.G522D | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV56205442; called by muse, mutect2, varscan2
- FBXL7 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs1256940003, COSV61654334; called by muse, mutect2, varscan2
- FMO3 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63008760; called by muse, mutect2, varscan2
- GAL3ST1 | c.903C>G p.N301K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58893804; called by muse, mutect2, varscan2
- GRM1 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 102/195 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763886921, COSV51110227; called by muse, mutect2, varscan2
- GSE1 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as rs1484804294, COSV53676745; called by muse, mutect2, varscan2
- IL17RE | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV55971156; called by muse, mutect2, varscan2
- ITPRID1 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs772590110, COSV60073092, COSV60084168; called by muse, mutect2, varscan2
- LRRIQ4 | c.969T>A p.C323* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs13062420, COSV61620421; called by muse, mutect2
- MBD5 | c.2503A>G p.T835A | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs770527493, COSV68699162; called by muse, mutect2, varscan2
- NONO | c.1084A>C p.M362L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV52140747; called by muse, mutect2
- OR4B1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs149306992; called by muse, mutect2, varscan2
- PABPC3 | c.754A>G p.N252D | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs200416454, COSV99879282; called by muse, mutect2, varscan2
- PCDH17 | c.1607C>A p.A536D | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64980274; called by muse, mutect2, varscan2
- PCDHGA4 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.639); catalogued as COSV54048076; called by muse, mutect2, varscan2
- PFKP | c.2282T>C p.L761P | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56540999; called by muse, mutect2, varscan2
- PITPNC1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs780864654, COSV55447603; called by muse, varscan2
- RBMX | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs748713750, COSV57811785; called by muse, mutect2
- RXRG | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); catalogued as COSV100717684, COSV63233297; called by muse, mutect2, varscan2
- SH3TC2 | c.1588C>G p.L530V | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.496); catalogued as COSV100101447; called by muse, mutect2, varscan2
- SLC2A4RG | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV55515633; called by muse, mutect2, varscan2
- SPTA1 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 42/169 reads (25%) | catalogued as rs757845058, COSV63760797; called by muse, mutect2, varscan2
- STK35 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55693226; called by muse, mutect2, varscan2
- TNPO1 | c.2503G>A p.G835S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61524332; called by muse, mutect2, varscan2
- USP14 | c.613A>C p.I205L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55283906; called by muse, mutect2, varscan2
- USP7 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as rs944748771, COSV61216802; called by muse, mutect2, varscan2
- VIPAS39 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.283); catalogued as rs199989629, COSV58942501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WWC2 | c.1616C>A p.A539D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV66717312; called by muse, mutect2, varscan2
- KIF13A | c.5228_5229del p.E1743Gfs*5 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by pindel, varscan2
- ADGRA3 | c.3852C>T p.N1284= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV51569222; called by muse, mutect2, varscan2
- ATP6V1C2 | c.699T>A p.I233= | Silent (SNP) | VAF 24/231 reads (10%) | catalogued as COSV55365724; called by muse, mutect2, varscan2
- H3C6 | c.318G>A p.E106= | Silent (SNP) | VAF 9/125 reads (7%) | catalogued as COSV64519487; called by muse, mutect2
- OR4A16 | c.255T>C p.C85= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as COSV100125169, COSV59041738; called by muse, mutect2
- POLDIP3 | c.897T>G p.L299= | Silent (SNP) | VAF 41/180 reads (23%) | catalogued as COSV52810471; called by muse, mutect2, varscan2
- IFRD2 | chr3:50292687 C>A | 5'Flank (SNP) | VAF 45/105 reads (43%) | catalogued as COSV100269379; called by muse, mutect2, varscan2
